Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A708, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A708-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology [OrderID:

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Adrenal, tumor, right, excision: Pheochromocytoma, see note.

NOTE: Staining for chromogranin and synaptophysin is postive.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief

Clinical History:

adrenal pheo Specimen Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: Pheochromocytoma Post-Operative

Diagnosis:

same Operative Findings: large right adrenal tumor

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT

GROSS DESCRIPTION:

Received fresh in a container labeled with patient's name, medical record number, and further specified as "right adrenal 6.5 x 6.5 x 5.5" is a 99g adrenalectomy specimen measuring 7.5 x 5.5 x 5.2 cm with attached adipose tissue. There is a 6 x 6 x 5.5-cm mass with a heterogeneous hemorrhagic soft and tan firm cut surface. Gross photographs are taken. Approximately 40% of tissue from the tan firm parenchyma is procured for and 10% of the tan firm tissue procured for. Approximately 1 x 0.5 x 0.5 cm of periadrenal adipose tissue is procured for. The procurement was performed by

The external surface is inked black. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The specimen is received in the Gross Pathology lab and matches the above description. Upon sectioning, one end of normal adrenal gland is observed. Within it, there is a small cortical nodule, with a yellow-tan cut surface measuring in greatest dimension 0.4 cm. A portion of the largest nodule has a hemorrhagic surface.

Summary of cassettes submitted for permanent processing:

A: Normal-appearing adrenal gland.

Confidential Patient Information. Unannounced disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 2]
Surgical Pathology

Final Results

- B: Normal-appearing adrenal gland with adjacent nodular area.
C: Representative section of large nodules with overlaying capsule.
D: Hemorrhagic portion of nodule with capsule.
E: Representative section of normal appearing gland with a subcapsular nodule.
F: Representative section of largest nodule with adjacent capsule and an adjacent blood vessel.
G: Representative section of nodule with adjacent capsule.
H: Representative section of nodule with adjacent capsule and subjacent hemorrhage.

Gross description dictated by .

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

HPI/A Discrepancy		☒

Source: NCI Genomic Data Commons file c8229686-c1ca-4ac2-b03a-f767afb0965a (TCGA-QR-A708.E8248729-742F-4355-A191-4B8754AEFDB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).